Somatic mutation profile of tumor specimen 0DI6KX from CCDI case PBBUYL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain stem; Age at diagnosis: 4.5 years (1,634 days).
Specimen 0DI6KX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3489ddff-7f8b-408f-b414-3e2e9e1dbf7b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI6KM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0686e5c-d01b-4c34-bdc9-70daa2ff3e73

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRF3 | c.2533G>A p.A845T (on ENST00000311519 / NM_001145168.1; = p.A646T on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 208/657 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs375056876; called by muse, varscan2
- KSR2 | c.2234G>T p.R745L | Missense Mutation (SNP) | VAF 302/1208 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.606); called by muse, varscan2
- NPHS1 | c.768G>A p.R256= | Silent (SNP) | VAF 162/1068 reads (15%) | catalogued as rs775136571; called by muse, varscan2
